Somatic mutation profile of tumor specimen TCGA-DA-A1HV-06A (aliquot TCGA-DA-A1HV-06A-21D-A196-08) from TCGA case TCGA-DA-A1HV, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 75.4 years (27,556 days).
Specimen TCGA-DA-A1HV-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d37e7585-d23d-4e3d-8810-cf40fcbde805.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1HV-10A (Blood Derived Normal), aliquot TCGA-DA-A1HV-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ab2dd67-f409-4a52-867d-c980f16a2ad4

The open-access MAF lists 1,665 somatic variants for this specimen: 1,068 protein-altering or splice-affecting, 554 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 974, Silent 554, Nonsense Mutation 62, RNA 18, Splice Site 16, Intron 13, Splice Region 11, 3'UTR 5, Frame Shift Del 4, 5'Flank 3, 5'UTR 2, 3'Flank 2.

Variants (750 of 1,665; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 154/234 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as CM970251, COSV100446243, COSV58683273, COSV58688196; called by muse, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 64/131 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 21/32 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2M | c.2139G>A p.M713I | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV59382890; called by muse, varscan2
- A4GALT | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50746947; called by muse, mutect2
- ABAT | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51629354; called by muse, mutect2, varscan2
- ABCA4 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV64679107; called by muse, mutect2, varscan2
- ABCA6 | c.4697-2A>C p.X1566_splice | Splice Site (SNP) | VAF 16/65 reads (25%) | catalogued as COSV52646313; called by muse, mutect2, varscan2
- ABCG8 | c.562-1G>A p.X188_splice | Splice Site (SNP) | VAF 51/137 reads (37%) | catalogued as COSV99700380; called by muse, mutect2, varscan2
- ABCG8 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767597558; called by muse, mutect2, varscan2
- ACAN | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV61370983; called by muse, mutect2, varscan2
- ACAN | c.4183C>T p.P1395S | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.327); catalogued as rs1392430936, COSV61370990; called by muse, varscan2
- ACOT7 | c.841C>T p.H281Y (on ENST00000377855 / NM_181864.3; = p.H271Y on NM_007274.4) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV64114159, COSV64114878; called by muse, mutect2, varscan2
- ACP1 | c.44-1G>A p.X15_splice | Splice Site (SNP) | VAF 53/108 reads (49%) | catalogued as COSV55245833; called by muse, mutect2, varscan2
- ACSM2A | c.740G>A p.G247D (on ENST00000219054; = p.G168D on NM_001308169.2) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.105); catalogued as COSV54583314; called by muse, mutect2, varscan2
- ACTL8 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV64861465, COSV64862128, COSV64862919; called by muse, mutect2, varscan2
- ACTRT1 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV64420165; called by muse, mutect2, varscan2
- ADAM11 | c.280A>C p.N94H | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV52350354; called by muse, mutect2, varscan2
- ADAM2 | c.1741C>T p.H581Y | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1292730440, COSV55862223; called by muse, mutect2, varscan2
- ADAM2 | c.268-1G>A p.X90_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | catalogued as rs868815201, COSV55869499; called by muse, mutect2
- ADAM20 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 23/32 reads (72%) | catalogued as rs778491103, COSV56456874; called by muse, mutect2, varscan2
- ADAM29 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 49/131 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV63667294; called by muse, mutect2, varscan2
- ADAMTS12 | c.4469G>A p.G1490D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710460, COSV61283044; called by muse, mutect2
- ADAMTS18 | c.2592G>A p.M864I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1293402616, COSV51424273; called by muse, mutect2, varscan2
- ADAMTS18 | c.2009G>A p.W670* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as rs1567484021, COSV51398703; called by muse, mutect2, varscan2
- ADAMTS8 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57298611; called by muse, mutect2, varscan2
- ADAMTS8 | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.4); PolyPhen benign (0.052); catalogued as COSV57298627; called by muse, varscan2
- ADCY8 | c.2595G>A p.M865I | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs267601770, COSV53921426; called by muse, mutect2, varscan2
- ADGRB3 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 35/95 reads (37%) | catalogued as COSV65424133; called by muse, mutect2, varscan2
- ADGRB3 | c.3521C>T p.S1174L | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs865786073, COSV53245625; called by muse, mutect2, varscan2
- ADGRF1 | c.2492G>A p.G831E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51948233; called by muse, mutect2, varscan2
- ADGRG4 | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 92/135 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.18); catalogued as COSV54969075; called by muse, mutect2, varscan2
- ADGRL4 | c.394A>G p.K132E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV66066825; called by muse, mutect2
- ADGRV1 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771784301, CM135898, COSV67996767; called by muse, mutect2, varscan2
- ADH1C | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV72463727; called by muse, mutect2, varscan2
- ADORA2B | c.423C>A p.F141L | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV58483779; called by muse, mutect2, varscan2
- ADRA2B | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs1214005786, COSV69788460; called by muse, mutect2, varscan2
- ADRA2B | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV69787692; called by muse, mutect2, varscan2
- ADTRP | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 53/190 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs758519538, COSV57642018; called by muse, mutect2, varscan2
- AFAP1L1 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57047391; called by muse, mutect2, varscan2
- AFAP1L1 | c.1586C>T p.T529I | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs748085177, COSV57048229; called by muse, mutect2, varscan2
- AGT | c.1122C>T p.P374= | Splice Region (SNP) | VAF 25/121 reads (21%) | catalogued as rs1012870153, COSV100794456, COSV64185636; called by muse, mutect2, varscan2
- AHNAK2 | c.16994C>T p.S5665F | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60933483; called by muse, mutect2, varscan2
- AHSP | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs1395094178, COSV56529622; called by muse, mutect2, varscan2
- AKAP9 | c.5687C>T p.T1896I (on ENST00000359028; = p.T1864I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV62359409; called by muse, mutect2
- AKR1C3 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV65911312; called by muse, mutect2, varscan2
- AL645922.1 | c.135C>G p.S45R | Missense Mutation (SNP) | VAF 96/408 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV54962923; called by muse, mutect2, varscan2
- AL645922.1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.999); catalogued as rs1408553211, COSV54962938; called by muse, mutect2, varscan2
- AL645922.1 | c.1574T>G p.V525G | Missense Mutation (SNP) | VAF 74/368 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54962942; called by muse, mutect2
- ALK | c.4481G>A p.G1494E | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs368484630; ClinVar: uncertain significance; called by muse, mutect2
- ALMS1 | c.8471C>T p.P2824L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs759511181, COSV52523860; called by muse, mutect2, varscan2
- ALOX5 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs560031203, COSV65550928; called by muse, mutect2, varscan2
- ALPL | c.474G>A p.G158= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as rs868361054, COSV66379762; called by muse, mutect2, varscan2
- ALS2 | c.2683T>C p.F895L | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV51893839; called by muse, mutect2, varscan2
- AMBN | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV59828365; called by muse, mutect2, varscan2
- AMBN | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV59828372; called by muse, mutect2, varscan2
- AMHR2 | c.1254G>A p.W418* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV57687254; called by muse, mutect2, varscan2
- AMPD1 | c.1679G>A p.S560N | Missense Mutation (SNP) | VAF 79/138 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs762142318, COSV62419546; called by muse, mutect2, varscan2
- ANK3 | c.3581G>A p.G1194E (on ENST00000280772 / NM_001320874.2; = p.G328E on NM_001149.3) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780524754, COSV55086063; called by muse, mutect2, varscan2
- ANKAR | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV55611076; called by muse, mutect2, varscan2
- ANKFN1 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 83/109 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV59461791; called by muse, mutect2, varscan2
- ANKRD24 | c.3244C>T p.P1082S | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV53676337; called by muse, mutect2, varscan2
- ANKRD45 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs865783054, COSV60962808; called by muse, mutect2, varscan2
- ANKRD45 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.025); catalogued as COSV60962822; called by muse, mutect2, varscan2
- ANKZF1 | c.1145G>A p.R382K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV55479469; called by muse, mutect2, varscan2
- AOC1 | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62871369; called by muse, mutect2, varscan2
- AOX1 | c.2497C>T p.R833C | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749776412, COSV65981358; called by muse, mutect2, varscan2
- AP1M2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778192600, COSV51569836; called by muse, mutect2, varscan2
- APAF1 | c.511C>T p.H171Y (on ENST00000551964 / NM_181861.2; = p.H160Y on NM_001160.3) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); catalogued as COSV54489730; called by mutect2, varscan2
- APOB | c.10586C>T p.S3529L | Missense Mutation (SNP) | VAF 148/618 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV51956291; called by muse, mutect2, varscan2
- ARFGEF2 | c.4556C>T p.P1519L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100904343, COSV64215717; called by muse, mutect2, varscan2
- ARHGAP29 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV53110737; called by muse, mutect2, varscan2
- ARHGEF12 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs764042487, COSV63107853; called by muse, mutect2, varscan2
- ARHGEF5 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs554814755, COSV50215082, COSV50221679; called by muse, mutect2, varscan2
- ARHGEF6 | c.1978C>T p.L660F | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51694974, COSV99166630; called by muse, mutect2, varscan2
- ARL4A | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.89); PolyPhen benign (0.159); catalogued as COSV63319702; called by muse, mutect2, varscan2
- ARMC1 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | catalogued as COSV52535061; called by muse, mutect2, varscan2
- ARMC4 | c.3055G>A p.D1019N | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.139); catalogued as COSV59456466, COSV59461306; called by muse, mutect2, varscan2
- ARMH4 | c.2066G>A p.W689* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV50776897, COSV99959104; called by muse, mutect2, varscan2
- ARPP21 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.429); catalogued as COSV51810085; called by muse, mutect2, varscan2
- ASB10 | c.1345C>T p.P449S (on ENST00000420175 / NM_001142459.2; = p.P434S on NM_080871.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV52001369; called by muse, mutect2, varscan2
- ASPG | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); catalogued as COSV71934203; called by muse, mutect2, varscan2
- ASTN2 | c.1331C>T p.S444F (on ENST00000313400 / NM_001365069.1; = p.S393F on NM_014010.5) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs866109686, COSV57764562; called by muse, mutect2, varscan2
- ASXL1 | c.2518C>T p.P840S | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.351); catalogued as COSV60124574; called by muse, mutect2, varscan2
- ATAD2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54887811; called by muse, mutect2, varscan2
- ATAD2 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs1405229522, COSV54887821; called by muse, mutect2, varscan2
- ATF4 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147899546, COSV57480972; called by muse, mutect2, varscan2
- ATP2C2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as COSV52302161; called by muse, mutect2, varscan2
- ATP8A2 | c.2207T>G p.L736W | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54979304; called by muse, mutect2, varscan2
- AXDND1 | c.2581C>T p.Q861* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV62650174; called by muse, mutect2, varscan2
- B3GALT5 | c.518A>T p.K173I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58200860; called by muse, mutect2, varscan2
- BAZ2B | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58611488; called by muse, mutect2, varscan2
- BBS4 | c.743C>A p.T248N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV51440818; called by muse, mutect2, varscan2
- BCAM | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 56/90 reads (62%) | catalogued as COSV54305526; called by muse, mutect2, varscan2
- BCL2 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as COSV61390472, COSV61397047; called by muse, mutect2, varscan2
- BCL6 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.18); catalogued as COSV51656304; called by muse, mutect2, varscan2
- BCL9L | c.3464C>T p.P1155L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1275999754, COSV52688191, COSV52689945; called by muse, mutect2, varscan2
- BCO1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50734839; called by muse, mutect2, varscan2
- BEND2 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.65); PolyPhen benign (0.101); catalogued as COSV66217614; called by muse, mutect2, varscan2
- BPIFB2 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as COSV50072128; called by muse, mutect2
- BRD1 | c.2362C>T p.L788F (on ENST00000216267 / NM_001349940.1; = p.L919F on NM_001304808.3) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.289); catalogued as COSV53456447; called by muse, mutect2, varscan2
- BTK | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 57/83 reads (69%) | catalogued as CD056796, CD108242, CM040385, CM133275, COSV58124295; called by muse, mutect2, varscan2
- C12orf50 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV53899563; called by muse, mutect2
- C1orf127 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV65439275; called by muse, mutect2, varscan2
- C1orf87 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs954642126, COSV64596002; called by muse, mutect2, varscan2
- C2CD3 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.13); catalogued as rs775127219, COSV58102679; called by muse, varscan2
- C3 | c.1954C>T p.Q652* | Nonsense Mutation (SNP) | VAF 33/54 reads (61%) | catalogued as COSV55582687; called by muse, mutect2, varscan2
- C4orf50 | c.584C>T p.P195L (on ENST00000324058; = p.P1427L on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV60691023; called by muse, mutect2, varscan2
- C5orf34 | c.422A>T p.H141L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV60932335; called by muse, mutect2, varscan2
- C6orf118 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 35/57 reads (61%) | catalogued as rs1422339097; called by muse, mutect2, varscan2
- C7 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.026); catalogued as rs370428541; called by muse, mutect2, varscan2
- C8B | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs759366974, COSV64780014; called by muse, mutect2, varscan2
- CACNA1I | c.2803C>T p.R935* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV60819999; called by muse, mutect2, varscan2
- CACNA1S | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62944680; called by muse, mutect2, varscan2
- CACNB4 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52405217; called by muse, mutect2, varscan2
- CALCR | c.668C>T p.P223L (on ENST00000649521 / NM_001164737.2; = p.P207L on NM_001742.4) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.84); catalogued as COSV64012833; called by muse, mutect2, varscan2
- CAMSAP3 | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV50375455; called by muse, mutect2, varscan2
- CATSPERD | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs757837954, COSV101062597, COSV67534240; called by muse, mutect2, varscan2
- CATSPERE | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV63676526; called by muse, mutect2, varscan2
- CBLB | c.1387C>T p.R463W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs779755160, COSV51422008; called by muse, mutect2, varscan2
- CBLL2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 74/114 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.445); catalogued as COSV60370738; called by muse, mutect2, varscan2
- CCDC130 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV50005731; called by muse, mutect2, varscan2
- CCDC141 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs267599098, COSV55384192; called by muse, mutect2, varscan2
- CCDC141 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV55368066; called by muse, mutect2, varscan2
- CCDC198 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs1385043953, COSV53603815; called by muse, mutect2, varscan2
- CCDC60 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.369); catalogued as COSV59551874; called by muse, varscan2
- CCDC81 | c.1099C>T p.L367F (on ENST00000445632 / NM_001156474.2; = p.L277F on NM_021827.4) | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV99563890; called by muse, mutect2, varscan2
- CCHCR1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 162/322 reads (50%) | SIFT tolerated (0.48); PolyPhen benign (0.04); catalogued as rs566793779, COSV66161484, COSV66161764; called by muse, mutect2, varscan2
- CCKAR | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs868034108, COSV55160045, COSV55164469; called by muse, mutect2, varscan2
- CCKBR | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV58100978; called by muse, mutect2, varscan2
- CCR2 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT tolerated (0.75); PolyPhen benign (0.06); catalogued as COSV52750423; called by muse, mutect2, varscan2
- CCT8L2 | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV63463684, COSV63464062; called by muse, mutect2, varscan2
- CD101 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs761625520, COSV56717401; called by muse, mutect2, varscan2
- CD300E | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 74/108 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200764407, COSV60791838, COSV60791987; called by muse, mutect2, varscan2
- CD33 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV51800727, COSV51802918; called by muse, mutect2, varscan2
- CD84 | c.917C>T p.P306L (on ENST00000311224 / NM_001184879.2; = p.P289L on NM_003874.4) | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV60871327; called by muse, mutect2, varscan2
- CDC25C | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.86); PolyPhen benign (0.111); catalogued as COSV60401508; called by muse, mutect2, varscan2
- CDCA7 | c.654G>A p.M218I (on ENST00000347703 / NM_145810.3; = p.M297I on NM_031942.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV60722008; called by mutect2, varscan2
- CDH10 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.019); catalogued as rs865864231, COSV52601365; called by muse, mutect2, varscan2
- CDH12 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 90/153 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs945820536, COSV101200656, COSV66455223; called by muse, mutect2, varscan2
- CDHR1 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV60567123; called by muse, mutect2, varscan2
- CDHR2 | c.1351-1G>A p.X451_splice | Splice Site (SNP) | VAF 17/32 reads (53%) | catalogued as COSV56146374; called by muse, mutect2, varscan2
- CDHR2 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.28); PolyPhen benign (0.194); catalogued as COSV56146386; called by muse, mutect2, varscan2
- CDYL2 | c.837C>T p.I279= | Splice Region (SNP) | VAF 5/10 reads (50%) | catalogued as rs748983597, COSV73654002, COSV73654452; called by muse, mutect2, varscan2
- CELSR1 | c.4649C>A p.S1550Y | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53090366, COSV53101563; called by muse, mutect2, varscan2
- CENPE | c.4996G>A p.E1666K | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as COSV54392271; called by muse, mutect2, varscan2
- CEP128 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 42/58 reads (72%) | catalogued as COSV53674882; called by muse, mutect2, varscan2
- CEP89 | c.1083G>A p.L361= | Splice Region (SNP) | VAF 66/123 reads (54%) | catalogued as rs769829028; called by muse, mutect2, varscan2
- CFAP44 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV55616527; called by muse, mutect2, varscan2
- CFAP52 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.919); catalogued as rs138429217; called by muse, mutect2, varscan2
- CFAP53 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as COSV68351364, COSV68352986; called by muse, mutect2, varscan2
- CFAP58 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57213846; called by muse, mutect2, varscan2
- CFAP69 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as rs572240323, COSV60188980; called by muse, mutect2, varscan2
- CFAP74 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.881); catalogued as COSV54575108; called by muse, varscan2
- CFH | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as CM105274, COSV62779044; called by muse, mutect2, varscan2
- CFH | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV66414497; called by muse, mutect2, varscan2
- CGB5 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.118); catalogued as COSV100032169; called by muse, mutect2, varscan2
- CHD7 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.017); catalogued as COSV71115287; called by mutect2, varscan2
- CHMP1A | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs201409761; called by muse, mutect2
- CHMP6 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 120/154 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57328329; called by muse, mutect2, varscan2
- CHMP7 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV57534104; called by muse, mutect2, varscan2
- CHRM2 | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV57786323; called by muse, mutect2, varscan2
- CIITA | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as CM970948, COSV60863175; called by muse, mutect2, varscan2
- CILP2 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52281216; called by muse, mutect2, varscan2
- CIP2A | c.2692C>T p.P898S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.018); catalogued as COSV55421743; called by muse, mutect2, varscan2
- CLEC17A | c.854A>T p.N285I | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV60430184; called by muse, mutect2, varscan2
- CLEC18C | c.1212-1G>A p.X404_splice | Splice Site (SNP) | VAF 17/44 reads (39%) | catalogued as COSV58501201; called by muse, mutect2, varscan2
- CLEC3A | c.317C>A p.S106Y (on ENST00000651443; = p.S97Y on NM_005752.6) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV55221285, COSV55224170; called by muse, mutect2, varscan2
- CLIP2 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV56287457; called by muse, varscan2
- CLIP2 | c.2084A>T p.E695V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV56287501; called by mutect2, varscan2
- CLN6 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99992652; called by muse, mutect2, varscan2
- CLTC | c.2933C>T p.A978V | Missense Mutation (SNP) | VAF 70/98 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV52253903; called by muse, mutect2, varscan2
- CNGA1 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs373782782; called by muse, mutect2, varscan2
- CNGB1 | c.2486G>A p.G829E | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51908043; called by muse, mutect2, varscan2
- CNKSR1 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV64164425; called by muse, mutect2, varscan2
- CNTN3 | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV55171557; called by muse, mutect2, varscan2
- CNTN3 | c.2126G>A p.G709E | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55186679; called by muse, mutect2, varscan2
- CNTNAP2 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.669); catalogued as COSV62268399; called by muse, varscan2
- CNTNAP2 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.519); catalogued as COSV62268404; called by muse, mutect2, varscan2
- COL11A1 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100617822, COSV62200878; called by muse, mutect2, varscan2
- COL13A1 | c.1021G>A p.G341R (on ENST00000398978 / NM_001130103.2; = p.G284R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV62576108; called by muse, mutect2, varscan2
- COL19A1 | c.1081-1G>A p.X361_splice | Splice Site (SNP) | VAF 22/57 reads (39%) | catalogued as rs748329939, COSV59567729, COSV59590966; called by muse, mutect2, varscan2
- COL24A1 | c.3841C>T p.P1281S | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV65312433, COSV65315714; called by muse, mutect2, varscan2
- COL25A1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs1405272630, COSV67651454; called by muse, mutect2, varscan2
- COL27A1 | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 25/27 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs992719609, COSV100621305, COSV61931440; called by muse, mutect2, varscan2
- COL28A1 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68085240; called by muse, mutect2, varscan2
- COL4A4 | c.3533G>A p.G1178D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61637333; called by mutect2, varscan2
- COL4A4 | c.3113G>A p.R1038K | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.545); catalogued as COSV61637338; called by muse, mutect2, varscan2
- COPB1 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.817); catalogued as COSV51451586; called by muse, mutect2, varscan2
- CPED1 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV60002453; called by muse, mutect2, varscan2
- CPED1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs767731316, COSV60005414; called by muse, mutect2, varscan2
- CPXM2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.403); catalogued as COSV53872353; called by muse, mutect2, varscan2
- CPXM2 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV53872365, COSV99581396; called by muse, mutect2, varscan2
- CR1 | c.4027G>A p.G1343R | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65459693; called by muse, mutect2, varscan2
- CREBBP | c.2782C>T p.P928S | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV52117641, COSV52122351; called by muse, mutect2, varscan2
- CRISP2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV59253803; called by muse, mutect2, varscan2
- CRYZ | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs1377940833, COSV61716870, COSV61718625; called by muse, varscan2
- CSGALNACT2 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65676481; called by muse, mutect2, varscan2
- CSMD1 | c.6839G>A p.G2280E (on ENST00000520002; = p.G2279E on NM_033225.6) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59395369; called by muse, mutect2
- CSMD1 | c.3251T>G p.L1084R (on ENST00000520002; = p.L1083R on NM_033225.6) | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV59395392; called by muse, mutect2, varscan2
- CSMD2 | c.8767G>A p.G2923R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV53971717; called by muse, mutect2, varscan2
- CSMD2 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53971737; called by muse, mutect2, varscan2
- CSRNP3 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.295); catalogued as COSV58783230; called by muse, mutect2, varscan2
- CTAGE1 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV66944257; called by muse, mutect2, varscan2
- CTF1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV53064705; called by muse, varscan2
- CTLA4 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361102216, COSV55593443; called by muse, mutect2, varscan2
- CUL7 | c.2783C>T p.S928F | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as COSV54823006; called by muse, mutect2, varscan2
- CWF19L2 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56521555, COSV99980190; called by muse, mutect2, varscan2
- CYP11A1 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51435361, COSV99069147; called by muse, mutect2, varscan2
- CYP2C19 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV64909754; called by muse, varscan2
- CYP2C19 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1280222346, COSV64909760; called by muse, mutect2, varscan2
- CYP39A1 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201855604, COSV51494975; called by muse, mutect2, varscan2
- CYP3A7 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60483731; called by muse, mutect2, varscan2
- CYP4Z1 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61966993; called by muse, varscan2
- CYSLTR1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV64820996; called by muse, mutect2, varscan2
- DAAM1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62838598; called by muse, mutect2, varscan2
- DBX1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs866316035, COSV57055507; called by muse, mutect2, varscan2
- DCAF12L2 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63584553; called by muse, mutect2, varscan2
- DCAF8L1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.074); catalogued as COSV71595141, COSV71595142; called by muse, mutect2, varscan2
- DCC | c.3061C>T p.R1021* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV59103256; called by muse, mutect2
- DCC | c.4162G>A p.G1388R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757310889, COSV71442260; called by muse, mutect2, varscan2
- DCDC2 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs370613808; called by muse, mutect2, varscan2
- DCHS1 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs771545363, COSV55044101; called by muse, mutect2, varscan2
- DCLK3 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as COSV101373976, COSV69365030; called by muse, mutect2, varscan2
- DDR2 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.332); catalogued as COSV63375015; called by muse, mutect2, varscan2
- DDR2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV63373066; called by muse, mutect2, varscan2
- DEFB112 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as rs747742414, COSV59183215; called by muse, mutect2, varscan2
- DENND5A | c.1304T>C p.L435P | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.571); catalogued as rs750848425, COSV60238495; called by muse, mutect2, varscan2
- DGKE | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs1242360342, COSV52351719; called by muse, mutect2, varscan2
- DGKI | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761224295, COSV55969021, COSV55969848; called by mutect2, varscan2
- DHRS7C | c.487C>T p.L163F (on ENST00000330255 / NM_001220493.2; = p.L162F on NM_001105571.3) | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57653091; called by muse, mutect2, varscan2
- DHRS9 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV59141937; called by muse, mutect2, varscan2
- DHX36 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV57677851; called by muse, mutect2, varscan2
- DICER1 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58629598; called by muse, mutect2, varscan2
- DIP2B | c.4706C>T p.P1569L | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56593475; called by muse, mutect2, varscan2
- DISP3 | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs377572784; called by muse, mutect2, varscan2
- DLGAP1 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV59790748; called by muse, mutect2, varscan2
- DLGAP4 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1348840860, COSV59421582; called by muse, mutect2, varscan2
- DLGAP4 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59417515; called by muse, mutect2, varscan2
- DLL4 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV51074321; called by muse, mutect2, varscan2
- DMBT1 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 74/310 reads (24%) | catalogued as rs1227952543, COSV57561635; called by muse, mutect2, varscan2
- DMBT1 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 122/262 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.089); catalogued as COSV57566400; called by muse, varscan2
- DMBT1 | c.1634G>A p.G545E | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs748561929, COSV57550234; called by muse, varscan2
- DMBT1 | c.1706A>T p.Y569F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV57566436; called by muse, mutect2, varscan2
- DMBT1 | c.7399C>T p.R2467C (on ENST00000338354 / NM_001377530.1; = p.R1710C on NM_004406.3) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs763374104, COSV57536571; called by muse, mutect2, varscan2
- DMWD | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as COSV52178364; called by muse, mutect2, varscan2
- DNAH1 | c.10751C>T p.S3584F | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV70237635; called by muse, mutect2, varscan2
- DNAH2 | c.5152C>T p.H1718Y | Missense Mutation (SNP) | VAF 171/277 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140523857, COSV66728622; called by muse, mutect2, varscan2
- DNAH3 | c.10621G>A p.D3541N | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54557532; called by muse, mutect2, varscan2
- DNAH5 | c.11116G>A p.E3706K | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54237741, COSV54257115; called by muse, mutect2, varscan2
- DNAH5 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs780952892, COSV54257141; called by muse, mutect2, varscan2
- DNAH7 | c.2724G>A p.M908I | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56749945, COSV56760028; called by muse, mutect2, varscan2
- DNAH7 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.04); catalogued as COSV56778606; called by muse, mutect2, varscan2
- DNAH8 | c.1304G>C p.G435A | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV59485452; called by muse, mutect2, varscan2
- DNAH8 | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV59457182; called by muse, mutect2
- DNAH8 | c.13022G>A p.R4341K | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs1196568176, COSV59485501; called by muse, mutect2, varscan2
- DNAH9 | c.11995G>A p.E3999K | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV52380895; called by muse, mutect2, varscan2
- DNAJC21 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 76/197 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57763033; called by muse, mutect2, varscan2
- DNER | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59170396; called by muse, mutect2, varscan2
- DNHD1 | c.11965G>A p.E3989K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363951037, COSV54444416; called by muse, mutect2, varscan2
- DOCK1 | c.3749C>T p.S1250L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs1055960911, COSV54732628; called by muse, mutect2, varscan2
- DOK6 | c.253C>T p.H85Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.106); catalogued as COSV66938610; called by muse, varscan2
- DOP1B | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.421); catalogued as COSV67696867; called by muse, mutect2, varscan2
- DPP4 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62110530; called by muse, mutect2, varscan2
- DPP4 | c.888G>A p.G296= | Splice Region (SNP) | VAF 27/46 reads (59%) | catalogued as rs565859811, COSV62105769, COSV62110535; called by muse, mutect2, varscan2
- DPP4 | c.536A>G p.N179S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV62110542; called by muse, mutect2, varscan2
- DPYS | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs533803158, COSV60908395; called by muse, mutect2, varscan2
- DSC2 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV51867726; called by muse, mutect2, varscan2
- DSCAM | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV68656529; called by muse, mutect2, varscan2
- DSG1 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57140022; called by muse, mutect2, varscan2
- DSG2 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV55203709; called by muse, mutect2, varscan2
- DSG3 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as rs779028572, COSV57130226; called by muse, mutect2, varscan2
- DSPP | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.328); catalogued as COSV56817556; called by muse, mutect2, varscan2
- DYDC2 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV55473790; called by muse, mutect2, varscan2
- DYM | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53994481; called by muse, mutect2, varscan2
- DYNAP | c.593C>T p.S198F (on ENST00000321600; = p.S172F on NM_173629.3) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV58666529; called by muse, mutect2, varscan2
- DYNC2H1 | c.1172T>A p.I391N | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.42); PolyPhen benign (0.116); catalogued as COSV62108916; called by muse, mutect2, varscan2
- EBF2 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV68780939; called by muse, mutect2, varscan2
- EDAR | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.997); catalogued as COSV51508563, COSV99303792; called by muse, mutect2, varscan2
- EDC4 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1417486432, COSV62768326; called by muse, mutect2, varscan2
- EDRF1 | c.3032C>T p.S1011L (on ENST00000356792 / NM_001202438.2; = p.S977L on NM_015608.2) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61766621; called by muse, mutect2, varscan2
- EFHB | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs564514351, COSV55544858; called by muse, mutect2, varscan2
- EIF2D | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV55113995; called by muse, mutect2, varscan2
- ELMO1 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.348); catalogued as COSV60328748; called by muse, mutect2, varscan2
- EMILIN3 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV60039141; called by muse, mutect2, varscan2
- ENGASE | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs550081329, COSV56138163; called by muse, mutect2, varscan2
- ENPP4 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58090325; called by muse, mutect2, varscan2
- ENPP6 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.454); catalogued as rs1214312825, COSV57068418, COSV57073249; called by muse, mutect2, varscan2
- EP400 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100202580; called by muse, varscan2
- EPB41 | c.518G>A p.G173E | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58055284; called by muse, mutect2, varscan2
- EPS8L2 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs1323935659, COSV59350516; called by muse, mutect2, varscan2
- ERCC6 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.751); catalogued as rs933666963, COSV63389943, COSV63394294; called by muse, mutect2, varscan2
- ERICH3 | c.2015G>A p.G672E | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773317691, COSV58620870; called by muse, mutect2, varscan2
- ESPNL | c.1648G>A p.V550I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV58038902; called by muse, mutect2, varscan2
- EVI5L | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV54489202; called by mutect2, varscan2
- EXOC3L1 | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as COSV52048696, COSV99333623; called by muse, mutect2, varscan2
- EXOSC9 | c.596T>A p.F199Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.789); catalogued as COSV54664917, COSV54668201; called by muse, mutect2, varscan2
- EYA3 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV65817989; called by muse, mutect2, varscan2
- EYS | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV61002061; called by muse, mutect2, varscan2
- F8 | c.3515G>A p.G1172E | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV64279527; called by muse, mutect2, varscan2
- FABP2 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56789476; called by muse, mutect2, varscan2
- FADS6 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59604064; called by muse, mutect2, varscan2
- FAM118A | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV53419879; called by muse, mutect2, varscan2
- FAM155A | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV65591079; called by muse, mutect2, varscan2
- FAM189A2 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as COSV57386484; called by muse, mutect2, varscan2
- FAM234B | c.776C>G p.A259G | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV52198202; called by muse, mutect2
- FANCI | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55535850; called by muse, mutect2, varscan2
- FARP2 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV50884543; called by muse, mutect2, varscan2
- FAT1 | c.5530C>T p.H1844Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); catalogued as COSV71676273; called by muse, mutect2, varscan2
- FAT3 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 215/391 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV53184841; called by muse, mutect2, varscan2
- FBLN5 | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV50910719; called by muse, mutect2, varscan2
- FBN1 | c.5732C>T p.S1911F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57332692; called by muse, mutect2, varscan2
- FCN2 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs1347967661, COSV52479403; called by muse, mutect2, varscan2
- FEM1B | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV60988183; called by muse, mutect2
- FES | c.1585C>T p.H529Y | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as COSV61001907; called by muse, mutect2, varscan2
- FGA | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); catalogued as COSV57402046; called by muse, mutect2, varscan2
- FGFR2 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60647224; called by muse, mutect2, varscan2
- FGR | c.242T>G p.L81R | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64969884; called by muse, mutect2, varscan2
- FILIP1 | c.2626A>T p.R876W | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV52742437; called by muse, varscan2
- FILIP1 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs760424277, COSV52742479; called by muse, mutect2, varscan2
- FLG | c.8302G>A p.E2768K | Missense Mutation (SNP) | VAF 59/552 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.431); catalogued as rs746938294, COSV64244968, COSV64251414; called by muse, mutect2, varscan2
- FLG | c.608G>A p.R203K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.323); catalogued as COSV64238985, COSV64251374, COSV64251423; called by muse, mutect2, varscan2
- FLG2 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV66174295; called by muse, mutect2, varscan2
- FLNA | c.3199C>T p.P1067S | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV61048295; called by muse, mutect2, varscan2
- FLT1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs755750116, COSV56734930; called by muse, mutect2, varscan2
- FMO4 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV63002044; called by muse, mutect2, varscan2
- FMOD | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV61610706; called by muse, mutect2, varscan2
- FMR1 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 71/120 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV54428018; called by muse, mutect2, varscan2
- FNDC1 | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.387); catalogued as rs1452555482, COSV51949298; called by muse, mutect2, varscan2
- FOXC2 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.299); catalogued as rs773245007, COSV57445549; called by muse, mutect2, varscan2
- FOXD4 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.548); catalogued as COSV58703622; called by muse, mutect2, varscan2
- FPR1 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs564702916, COSV59051589; called by muse, mutect2, varscan2
- FREM1 | c.3250A>T p.K1084* | Nonsense Mutation (SNP) | VAF 10/12 reads (83%) | catalogued as COSV66531565; called by muse, mutect2, varscan2
- FRG2B | c.416A>T p.E139V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV71044280; called by muse, varscan2
- FRMD1 | c.1331G>A p.G444D | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as COSV51965467; called by muse, mutect2, varscan2
- FRMD1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51961293, COSV51965491; called by muse, mutect2, varscan2
- FRMPD2 | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59724508; called by mutect2, varscan2
- FRY | c.6889C>T p.L2297F | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66570519; called by muse, mutect2, varscan2
- FRYL | c.3674A>C p.E1225A | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV51964454; called by muse, mutect2, varscan2
- FSD2 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs767355163, COSV58013603; called by muse, mutect2
- FURIN | c.2093T>G p.V698G | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51580226; called by muse, mutect2, varscan2
- FUT9 | c.152A>T p.K51I | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV56156360, COSV56158803; called by muse, mutect2, varscan2
- GABRG1 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV54962988; called by muse, mutect2, varscan2
- GALNT1 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52455279; called by muse, mutect2, varscan2
- GALNT17 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 120/214 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs867094025, COSV100356756, COSV61196496; called by muse, mutect2, varscan2
- GATB | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755309364, COSV56134106; called by muse, mutect2, varscan2
- GBF1 | c.4672C>G p.R1558G (on ENST00000369983 / NM_001377137.1; = p.R1557G on NM_004193.3) | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64149699; called by muse, varscan2
- GBP6 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65010875; called by muse, mutect2, varscan2
- GCOM1 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as rs866893705, COSV51092279, COSV51100482; called by muse, mutect2, varscan2
- GDAP2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766549019, COSV65611886; called by muse, mutect2, varscan2
- GGT5 | c.1261G>A p.G421S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54072976; called by muse, varscan2
- GIGYF2 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65254070; called by muse, mutect2, varscan2
- GIN1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 68/115 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs1364560153, COSV67536718; called by muse, mutect2, varscan2
- GLI2 | c.3136C>T p.P1046S (on ENST00000361492 / NM_001374353.1; = p.P1063S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV58052901; called by muse, mutect2, varscan2
- GLP1R | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV64716676; called by muse, mutect2, varscan2
- GPAM | c.2182T>A p.L728M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.387); catalogued as COSV62082884; called by mutect2, varscan2
- GPR12 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV67344875; called by muse, varscan2
- GPR142 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 81/104 reads (78%) | catalogued as COSV59520655; called by muse, mutect2, varscan2
- GPR155 | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV55042727; called by muse, mutect2, varscan2
- GPR182 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 142/227 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as COSV55625941; called by muse, mutect2, varscan2
- GPR27 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as COSV55207478; called by muse, mutect2
- GPR50 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as COSV54443651; called by muse, mutect2, varscan2
- GPRC6A | c.2765G>A p.R922K | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); catalogued as COSV59951386, COSV59956460; called by muse, mutect2, varscan2
- GRAMD1B | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV59211565; called by muse, mutect2, varscan2
- GREB1 | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs373266396; called by muse, mutect2, varscan2
- GRIA2 | c.2573C>T p.S858F | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV52409083; called by muse, mutect2, varscan2
- GRID1 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV60014191, COSV60058751; called by muse, mutect2, varscan2
- GRID2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV56279674; called by muse, mutect2, varscan2
- GRIN2A | c.4231T>G p.Y1411D | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58059289; called by muse, mutect2, varscan2
- GRM3 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.216); catalogued as COSV64466918; called by muse, mutect2, varscan2
- GRP | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); catalogued as COSV56880712; called by muse, mutect2, varscan2
- H6PD | c.1399C>T p.H467Y | Missense Mutation (SNP) | VAF 81/145 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1311109266, COSV66230344; called by muse, mutect2, varscan2
- HCK | c.158C>G p.P53R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52947863; called by muse, mutect2, varscan2
- HCN1 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1477444033, COSV100301983, COSV57520811; called by muse, mutect2, varscan2
- HCRTR2 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63799630; called by muse, mutect2, varscan2
- HDAC8 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65228120; called by muse, mutect2, varscan2
- HEATR4 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV58578056; called by muse, mutect2, varscan2
- HECW2 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV53670855; called by muse, mutect2, varscan2
- HEPH | c.361C>T p.R121C (on ENST00000343002; = p.R175C on NM_138737.5) | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1202646859, COSV57965409; called by muse, mutect2, varscan2
- HEPH | c.3292A>T p.M1098L (on ENST00000343002; = p.M831L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.71); PolyPhen benign (0.039); catalogued as COSV57973832; called by muse, mutect2, varscan2
- HGFAC | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as rs775909849, COSV66977391; called by muse, mutect2, varscan2
- HIF3A | c.1484C>T p.S495F (on ENST00000377670 / NM_152795.4; = p.S426F on NM_022462.4) | Missense Mutation (SNP) | VAF 48/64 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52205746; called by muse, mutect2, varscan2
- HIPK2 | c.2810C>T p.S937F | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV61233484; called by muse, mutect2, varscan2
- HLA-C | c.931A>T p.I311F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV66119696; called by muse, mutect2, varscan2
- HMCN1 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV54947945; called by muse, mutect2, varscan2
- HNRNPCL1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV58615576; called by mutect2, varscan2
- HOMER3 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV55359111; called by muse, mutect2, varscan2
- HOXA1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1249779889, COSV56068032; called by muse, mutect2, varscan2
- HOXC11 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 83/172 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV54533925; called by muse, mutect2, varscan2
- HS1BP3 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV58313674; called by muse, mutect2, varscan2
- HSD17B3 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1277790058, COSV64557999; called by muse, mutect2, varscan2
- HSPG2 | c.12800G>A p.G4267E | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766278882, COSV60829873; called by muse, mutect2, varscan2
- HTR7 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0.013); catalogued as COSV53291153; called by muse, mutect2, varscan2
- HTRA3 | c.1056G>A p.W352* | Nonsense Mutation (SNP) | VAF 25/64 reads (39%) | catalogued as rs757821112, COSV56473768; called by muse, mutect2, varscan2
- HYDIN | c.1376C>T p.P459L | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55501716; called by muse, mutect2, varscan2
- IARS2 | c.2494C>T p.R832C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56957822; called by muse, mutect2, varscan2
- IARS2 | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.187); catalogued as COSV56964917; called by muse, mutect2, varscan2
- ICA1 | c.1275C>A p.F425L | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV55585270; called by muse, mutect2, varscan2
- IGKV3-11 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758486991; called by muse, mutect2, varscan2
- IGLV3-22 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs530284832; called by muse, mutect2, varscan2
- IGSF9 | c.1819C>T p.P607S (on ENST00000368094 / NM_001135050.2; = p.P591S on NM_020789.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV63643014; called by muse, mutect2, varscan2
- IL15 | c.206T>A p.I69N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV56728574; called by muse, mutect2, varscan2
- IL16 | c.2857C>T p.Q953* (on ENST00000302987 / NM_172217.5; = p.Q252* on NM_004513.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV57269093; called by muse, mutect2, varscan2
- IL18R1 | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52124148, COSV52127657; called by muse, mutect2, varscan2
- IL21R | c.1579C>T p.P527S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV61969438; called by muse, mutect2, varscan2
- IL22 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV60160916; called by muse, mutect2, varscan2
- IL2RA | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as rs1438968487, COSV56922108; called by muse, mutect2, varscan2
- IL7R | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57406650; called by muse, mutect2, varscan2
- INAVA | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1414210952, COSV66256233, COSV66257765; called by muse, mutect2, varscan2
- INHBA | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.142); catalogued as rs1355421314, COSV54225763; called by muse, mutect2, varscan2
- INHBC | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.037); catalogued as COSV59005479; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1241C>T p.S414F (on ENST00000485419 / NM_001197113.1; = p.S338F on NM_014575.3) | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61862645; called by muse, mutect2, varscan2
- IRF5 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.027); catalogued as COSV50857327; called by muse, mutect2, varscan2
- ISLR | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV51435708; called by muse, mutect2, varscan2
- ISM2 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1353829006, COSV53635887; called by muse, mutect2, varscan2
- ITGA8 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.461); catalogued as COSV65223985; called by muse, mutect2, varscan2
- ITGAL | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV63324792; called by muse, mutect2, varscan2
- ITGAV | c.2524C>T p.L842F | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.526); catalogued as COSV53720141; called by muse, mutect2, varscan2
- ITPR2 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV54388027; called by muse, mutect2, varscan2
- ITPRID2 | c.3116C>T p.P1039L | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.116); catalogued as rs555805993, COSV57477181; called by muse, mutect2, varscan2
- ITSN1 | c.5140G>A p.D1714N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV67157725; called by muse, varscan2
- ITSN2 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs999374892, COSV61954831; called by muse, mutect2, varscan2
- JAK3 | c.2734G>A p.D912N | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV71688059; called by muse, mutect2, varscan2
- JAKMIP3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1473889029, COSV53830362; called by muse, mutect2, varscan2
- JAML | c.77C>T p.S26F (on ENST00000356289 / NM_001098526.2; = p.S16F on NM_153206.3) | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV52627584; called by muse, mutect2, varscan2
- JARID2 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1338979330, COSV59199845; called by muse, mutect2
- KCNB1 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 71/327 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.169); catalogued as rs868690306, COSV65571336; called by muse, mutect2, varscan2
- KCND2 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 99/174 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV58607562; called by muse, mutect2, varscan2
- KCNJ3 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54546339; called by muse, mutect2, varscan2
- KCTD8 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as rs1418351383, COSV63589315; called by muse, mutect2, varscan2
- KDSR | c.694-1G>A p.X232_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as rs1372803284, COSV58508471; called by muse, mutect2, varscan2
- KHDRBS2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV55489420; called by muse, mutect2, varscan2
- KIAA0319 | c.1115G>A p.W372* | Nonsense Mutation (SNP) | VAF 73/164 reads (45%) | catalogued as COSV65502433; called by muse, mutect2, varscan2
- KIAA0408 | c.690A>T p.E230D | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV64109161; called by muse, mutect2, varscan2
- KIAA1109 | c.2401C>T p.H801Y | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV52691807; called by muse, mutect2, varscan2
- KIF1A | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57504020; called by mutect2, varscan2
- KIF2C | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64765807; called by muse, mutect2, varscan2
- KIF4A | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV65546371; called by muse, mutect2, varscan2
- KLF12 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as COSV66573281; called by muse, mutect2, varscan2
- KLF15 | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56181301; called by muse, mutect2, varscan2
- KMT2D | c.14254T>A p.F4752I | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV56493364; called by muse, mutect2, varscan2
- KRT16 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV56970060; called by muse, mutect2, varscan2
- KRT4 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1447053471, COSV53407236; called by muse, varscan2
- KRT7 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59333389; called by muse, mutect2, varscan2
- KRT7 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV57767654; called by muse, mutect2, varscan2
- KRT72 | c.1191C>G p.H397Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV53377357, COSV99537440; called by muse, mutect2, varscan2
- KRT78 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV58854043; called by muse, mutect2, varscan2
- KRT83 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV53342921; called by muse, mutect2, varscan2
- KRTAP3-3 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV66956643; called by muse, mutect2, varscan2
- KYNU | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV51592918, COSV99933821; called by muse, mutect2, varscan2
- L1TD1 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.113); catalogued as rs765706497, COSV63134398; called by muse, mutect2, varscan2
- L3MBTL3 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62389301; called by muse, mutect2, varscan2
- LAMA2 | c.8176G>A p.E2726K | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV70356638; called by muse, mutect2, varscan2
- LARP4B | c.1684T>A p.S562T | Missense Mutation (SNP) | VAF 111/250 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV60224452; called by muse, mutect2, varscan2
- LAYN | c.941C>T p.S314L (on ENST00000375615 / NM_001258390.1; = p.S306L on NM_178834.5) | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866324427, COSV65105735; called by muse, mutect2, varscan2
- LCT | c.4822C>T p.P1608S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.274); catalogued as COSV51558796, COSV51559490; called by muse, mutect2, varscan2
- LEPR | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV62752809; called by muse, mutect2, varscan2
- LGALS9B | c.692C>T p.T231I (on ENST00000423676 / NM_001367292.1; = p.T230I on NM_001042685.2) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV60866048; called by muse, mutect2, varscan2
- LGI1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV65059546; called by muse, mutect2, varscan2
- LHPP | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV64331894; called by muse, mutect2, varscan2
- LILRB5 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs759401972, COSV60261614; called by muse, mutect2, varscan2
- LIPI | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776639602, COSV60711829; called by muse, mutect2, varscan2
- LNX1 | c.2131G>A p.E711K (on ENST00000263925 / NM_001126328.3; = p.E615K on NM_032622.2) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV55783893, COSV55785798; called by muse, mutect2, varscan2
- LRFN2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1370199799, COSV57829960; called by muse, mutect2, varscan2
- LRIG1 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs1054086085, COSV56249478; called by muse, mutect2, varscan2
- LRIT1 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 13/15 reads (87%) | catalogued as rs761755166, COSV63893828, COSV63893935; called by muse, mutect2, varscan2
- LRP1 | c.11090C>T p.P3697L | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV54528779; called by muse, mutect2, varscan2
- LRP1B | c.10424C>T p.T3475I | Missense Mutation (SNP) | VAF 50/88 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67260881, COSV67282543; called by muse, mutect2, varscan2
- LRP1B | c.4032G>A p.W1344* | Nonsense Mutation (SNP) | VAF 44/111 reads (40%) | catalogued as COSV67282546; called by muse, mutect2, varscan2
- LRP1B | c.2441G>A p.G814E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs775281520, COSV67282551; called by muse, mutect2, varscan2
- LRP2 | c.5623G>A p.G1875S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.087); catalogued as COSV55578426; called by muse, mutect2, varscan2
- LRP5 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.933); catalogued as COSV53724771; called by muse, mutect2, varscan2
- LRRC10 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64060809; called by muse, mutect2, varscan2
- LRRC14B | c.1112G>A p.G371D | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV52056596; called by muse, mutect2, varscan2
- LRRC43 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371846622; called by muse, mutect2, varscan2
- LRRC43 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV60293997; called by muse, mutect2, varscan2
- LRRIQ3 | c.619T>G p.S207A | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV63051075; called by muse, mutect2, varscan2
- LRRIQ4 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV61619267; called by muse, varscan2
- LTBP1 | c.4738C>T p.P1580S (on ENST00000404816 / NM_206943.4; = p.P1254S on NM_000627.4) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs760814029, COSV55386650; called by muse, mutect2, varscan2
- LTBP1 | c.4974G>A p.M1658I (on ENST00000404816 / NM_206943.4; = p.M1332I on NM_000627.4) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55386683; called by muse, mutect2, varscan2
- LTBP2 | c.4175G>A p.G1392E | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.46); PolyPhen benign (0.074); catalogued as COSV56215068; called by muse, mutect2, varscan2
- LTK | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs770047590, COSV53029635; called by muse, mutect2, varscan2
- LY6H | c.251T>A p.F84Y | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.973); catalogued as COSV61371670; called by muse, mutect2, varscan2
- LY9 | c.1368G>A p.W456* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV54435446, COSV54438547; called by muse, mutect2, varscan2
- MACF1 | c.7876C>T p.P2626S | Missense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV57148789; called by muse, mutect2, varscan2
- MAGEA3 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.811); catalogued as rs782041540, COSV64756629; called by muse, mutect2, varscan2
- MAGEA6 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 75/126 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100263034; called by muse, mutect2, varscan2
- MAGEB18 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV57465290; called by muse, mutect2, varscan2
- MAGI2 | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV62704223; called by muse, mutect2, varscan2
- MAP3K15 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58826055; called by muse, mutect2, varscan2
- MAP3K20 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs769862837, COSV64381013; called by muse, mutect2, varscan2
- MASP1 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61831429; called by muse, mutect2, varscan2
- MBL2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV64758104; called by muse, mutect2, varscan2
- MC4R | c.941A>G p.K314R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.101); catalogued as COSV55353509; called by muse, mutect2, varscan2
- MCM10 | c.656C>T p.S219F (on ENST00000484800 / NM_182751.3; = p.S218F on NM_018518.5) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV66337244; called by muse, mutect2, varscan2
- MED12 | c.5422C>T p.R1808W | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs372271659, COSV61358527; called by muse, mutect2, varscan2
- MED23 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV63437942; called by muse, mutect2, varscan2
- MEOX1 | c.706T>A p.S236T | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV59357581; called by muse, mutect2, varscan2
- METTL24 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58824936; called by muse, mutect2, varscan2
- MFSD6 | c.2312G>A p.S771N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs778604042, COSV55626026; called by muse, mutect2, varscan2
- MGAM | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866544940, COSV72074972; called by muse, mutect2, varscan2
- MGAM | c.4334C>T p.P1445L | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV72076076; called by muse, mutect2, varscan2
- MGAM | c.5128C>T p.H1710Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV72076001; called by muse, mutect2, varscan2
- MICALL1 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.367); catalogued as COSV53243808; called by muse, mutect2, varscan2
- MICU1 | c.1363C>T p.R455C (on ENST00000361114 / NM_001195518.2; = p.R461C on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs772587119, COSV100741699, COSV63148367; called by muse, mutect2, varscan2
- MINDY3 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV53218165, COSV53222635; called by muse, mutect2, varscan2
- MLC1 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as rs202135704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP11 | c.1460T>C p.F487S | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV53158294; called by muse, mutect2, varscan2
- MMP16 | c.1489G>A p.G497S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV54156727, COSV54193136; called by muse, mutect2, varscan2
- MMP25 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60681642; called by muse, mutect2, varscan2
- MMP3 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs782395032, COSV55408499; called by muse, mutect2, varscan2
- MMRN1 | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs745711366, COSV53338551; called by mutect2, varscan2
- MOBP | c.298C>T p.P100S (on ENST00000420739; = p.P124S on NM_001278322.2) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | PolyPhen probably damaging (0.932); catalogued as COSV60653794, COSV60655725; called by muse, varscan2
- MORC4 | c.2165G>C p.R722P | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as rs149926328, COSV55247353; called by muse, mutect2, varscan2
- MPP6 | c.125A>C p.E42A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV56043821; called by muse, mutect2, varscan2
- MPPED2 | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 20/29 reads (69%) | catalogued as COSV63901781; called by muse, mutect2, varscan2
- MR1 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs762295481, COSV51582415; called by muse, mutect2, varscan2
- MRTFA | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 148/304 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62931221; called by muse, mutect2, varscan2
- MSH5 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 177/618 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV65211953; called by muse, mutect2, varscan2
- MTBP | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV59966423; called by muse, mutect2, varscan2
- MTCL1 | c.2612T>A p.L871Q (on ENST00000306329 / NM_001378206.1; = p.L511Q on NM_015210.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60412940; called by muse, mutect2, varscan2
- MTNR1B | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 129/206 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs753927032, COSV57066806; called by muse, mutect2, varscan2
- MTOR | c.4922C>T p.S1641F | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772556623, COSV63875974; called by muse, varscan2
- MTOR | c.3804C>T p.A1268= | Splice Region (SNP) | VAF 5/22 reads (23%) | catalogued as COSV63879314; called by muse, mutect2, varscan2
- MTTP | c.2132G>A p.S711N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV55510553; called by muse, mutect2, varscan2
- MUC16 | c.41098G>A p.A13700T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.961); catalogued as COSV66697377; called by muse, mutect2, varscan2
- MUC16 | c.40982A>C p.N13661T | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as COSV66697389; called by muse, mutect2, varscan2
- MUC16 | c.20843C>T p.S6948F | Missense Mutation (SNP) | VAF 68/109 reads (62%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as COSV67458145; called by muse, mutect2, varscan2
- MUC16 | c.20120C>T p.S6707F | Missense Mutation (SNP) | VAF 74/124 reads (60%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV67500052; called by muse, mutect2, varscan2
- MUC16 | c.3911C>T p.S1304L | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV67452375; called by muse, mutect2, varscan2
- MUC17 | c.10795C>T p.P3599S | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.594); catalogued as COSV60290482; called by muse, mutect2, varscan2
- MUC17 | c.11126C>T p.S3709F | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767095770, COSV60306636; called by muse, mutect2, varscan2
- MUC3A | c.7694C>T p.S2565F | Missense Mutation (SNP) | VAF 80/463 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV60216026; called by muse, mutect2
- MUC4 | c.2375C>T p.S792F | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as rs1282901368, COSV62204382; called by muse, mutect2, varscan2
- MXRA5 | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 83/136 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV54253819; called by muse, mutect2, varscan2
- MYCBP2 | c.11540C>T p.S3847L (on ENST00000357337; = p.S3885L on NM_015057.5) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV62042358; called by muse, mutect2, varscan2
- MYCL | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as rs1198444872, COSV100862279, COSV65693508; called by muse, mutect2, varscan2
- MYF6 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.9); catalogued as COSV57353797; called by muse, mutect2, varscan2
- MYH11 | c.2523G>A p.V841= | Splice Region (SNP) | VAF 20/38 reads (53%) | catalogued as COSV55572737; called by muse, mutect2, varscan2
- MYH2 | c.4984C>T p.H1662Y | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs867066856, COSV55443562; called by muse, mutect2, varscan2
- MYH2 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV55449387, COSV55450465; called by muse, mutect2, varscan2
- MYH8 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 81/134 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67973947; called by muse, mutect2, varscan2
- MYO16 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.546); catalogued as rs372976718, COSV51822578; called by muse, mutect2, varscan2
- MYO19 | c.1298A>G p.Y433C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747480235; called by muse, mutect2, varscan2
- MYO5C | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55912832; called by muse, mutect2, varscan2
- MYO5C | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1331159911, COSV55912845; called by muse, mutect2, varscan2
- MYO9A | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); catalogued as COSV61859497; called by muse, mutect2, varscan2
- MYOC | c.383G>C p.R128P | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV50673903, COSV50674762, COSV50680547; called by muse, varscan2
- MYOF | c.5572G>A p.E1858K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771346954, COSV63706991; called by muse, mutect2, varscan2
- MYOM2 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV50791746; called by muse, mutect2, varscan2
- MYOM2 | c.3100T>C p.F1034L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs935682128, COSV50791845; called by muse, mutect2, varscan2
- MYOM2 | c.3991C>T p.Q1331* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100036434, COSV50791972; called by muse, mutect2
- MYPN | c.3539A>G p.N1180S | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62740904; called by muse, mutect2, varscan2
- N6AMT1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as COSV58133767; called by muse, mutect2, varscan2
- NAP1L2 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65172462; called by muse, mutect2, varscan2
- NAP1L3 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV59078027; called by muse, mutect2, varscan2
- NCAN | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV53060619; called by muse, mutect2, varscan2
- NEB | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.997); catalogued as rs751681905, COSV51351494; called by muse, mutect2, varscan2
- NEFM | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs1313276550, COSV55335409; called by muse, mutect2, varscan2
- NEK5 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV62882302; called by muse, mutect2, varscan2
- NEK8 | c.892A>T p.I298F | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1444939975, COSV52049356; called by muse, mutect2, varscan2
- NETO1 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.991); catalogued as COSV55016579; called by muse, mutect2, varscan2
- NEUROD4 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV54474622; called by muse, mutect2, varscan2
- NEXMIF | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV50173998; called by muse, mutect2, varscan2
- NHLRC2 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65176352; called by muse, mutect2, varscan2
- NLGN4X | c.1503G>A p.M501I | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as COSV52021445; called by muse, mutect2, varscan2
- NLRP13 | c.2887G>A p.D963N | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as rs267605701, COSV61620184; called by muse, mutect2, varscan2
- NLRP4 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs868450451, COSV56715942; called by muse, mutect2, varscan2
- NLRP8 | c.1477C>T p.L493F | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.752); catalogued as COSV52595109; called by muse, mutect2, varscan2
- NLRP9 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV60468542; called by muse, mutect2, varscan2
- NNT | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs201228453, COSV52928487; called by muse, varscan2
- NOL4 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52341910; called by muse, mutect2, varscan2
- NOTCH3 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV54625894; called by muse, mutect2, varscan2
- NOX1 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54197059; called by muse, mutect2, varscan2
- NPAP1 | c.2386C>T p.P796S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs867947556, COSV61508908; called by muse, mutect2, varscan2
- NPAP1 | c.2717G>A p.G906E | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.259); catalogued as COSV61512261; called by muse, mutect2, varscan2
- NPAS3 | c.413C>T p.P138L (on ENST00000356141 / NM_001164749.2; = p.P106L on NM_022123.3) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV58117131; called by muse, mutect2, varscan2
- NPSR1 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62208539; called by muse, varscan2
- NR1H4 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as COSV51857656; called by muse, mutect2, varscan2
- NRAP | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV63494634; called by muse, mutect2, varscan2
- NRG1 | c.1652A>C p.K551T (on ENST00000405005 / NM_013964.5; = p.K556T on NM_013956.5) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55178442; called by muse, mutect2, varscan2
- NRP1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55179097; called by muse, mutect2, varscan2
- NUTM1 | c.2272G>A p.G758S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV59219673; called by muse, mutect2, varscan2
- NYAP1 | c.1573C>T p.L525F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.984); catalogued as rs1402172238, COSV100278497, COSV55722630; called by muse, mutect2, varscan2
- OGDHL | c.2456C>T p.S819F | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs757577439, COSV65105128; called by muse, mutect2, varscan2
- OGT | c.2137C>T p.P713S | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV65482927; called by muse, mutect2, varscan2
- OR10G2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV73390486; called by muse, mutect2
- OR10G7 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1456940965, COSV57867089; called by mutect2, varscan2
- OR10H1 | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV58472300, COSV58473307; called by muse, mutect2, varscan2
- OR10H4 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV59063284; called by muse, mutect2, varscan2
- OR10J5 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58387454, COSV58387968; called by muse, mutect2, varscan2
- OR10K2 | c.769T>A p.F257I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV59222347, COSV59223040; called by muse, mutect2, varscan2
- OR10K2 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV59221948; called by muse, mutect2, varscan2
- OR10K2 | c.26T>G p.V9G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV59223056; called by muse, mutect2, varscan2
- OR13C3 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV66165692, COSV66166418; called by muse, mutect2, varscan2
- OR13C8 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 36/56 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV58612701; called by muse, mutect2, varscan2
- OR1K1 | c.814G>A p.G272S | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV52957457; called by muse, mutect2, varscan2
- OR2G6 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as rs757443337, COSV58573906, COSV58574355; called by muse, mutect2, varscan2
- OR2J3 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65849827; called by muse, mutect2, varscan2
- OR2M2 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 95/196 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1248784040, COSV62899590; called by muse, mutect2, varscan2
- OR2M7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.074); catalogued as rs267598502, COSV58739668; called by muse, mutect2, varscan2
- OR2T10 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV57898649; called by muse, mutect2, varscan2
- OR2T12 | c.713C>A p.T238N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58777473, COSV58779934; called by muse, varscan2
- OR2T33 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58818332; called by mutect2, varscan2
- OR2W1 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV65851430, COSV65852035; called by muse, mutect2, varscan2
- OR4A5 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as COSV60525083; called by muse, mutect2, varscan2
- OR4D5 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs768699202, COSV58305938; called by muse, mutect2, varscan2
- OR4D5 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58309328, COSV58309927; called by muse, mutect2, varscan2
- OR51B6 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV66514056; called by muse, mutect2, varscan2
- OR51E2 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67807777; called by muse, mutect2, varscan2
- OR5B3 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV58676285, COSV58678961; called by muse, mutect2, varscan2
- OR5F1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53546084; called by muse, mutect2, varscan2
- OR5H2 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1199536934, COSV62352097; called by muse, mutect2, varscan2
- OR5T3 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV57380207; called by muse, mutect2, varscan2
- OR5T3 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as rs759592718, COSV57382571; called by muse, mutect2, varscan2
- OR5V1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs867652492, COSV65830848; called by muse, mutect2, varscan2
- OR6C1 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65573214, COSV65574627; called by muse, mutect2, varscan2
- OR6C2 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.882); catalogued as rs1342559489, COSV59517188; called by muse, mutect2, varscan2
- OR6F1 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.062); catalogued as COSV57467315, COSV57469745; called by muse, mutect2, varscan2
- OR7G1 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV53319231; called by muse, mutect2, varscan2
- OR8D4 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs867554307, COSV58429605; called by muse, mutect2, varscan2
- OR9Q2 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1307795409, COSV61112940; called by muse, mutect2, varscan2
- OSBPL6 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 70/119 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV51932647; called by muse, varscan2
- OSMR | c.2045-1G>A p.X682_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV57081052, COSV57093069; called by muse, mutect2, varscan2
- OTOF | c.2604G>T p.K868N (on ENST00000272371 / NM_194248.3; = p.K121N on NM_004802.4) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV55523094; called by muse, mutect2, varscan2
- OXR1 | c.1660C>T p.R554* (on ENST00000442977 / NM_001198532.1; = p.R553* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV56328569; called by muse, mutect2, varscan2
- P3H2 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1307588537, COSV60027650; called by muse, mutect2, varscan2
- PABPN1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs143507010; called by muse, mutect2, varscan2
- PADI6 | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs371023394; called by muse, mutect2, varscan2
- PAK5 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs942131023, COSV62025855; called by muse, mutect2, varscan2
- PAK5 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV62020628; called by muse, mutect2, varscan2
- PAPLN | c.2210C>T p.P737L (on ENST00000554301; = p.P710L on NM_173462.4) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53713323, COSV99389054; called by muse, mutect2, varscan2
- PAXBP1 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV51612810; called by muse, mutect2, varscan2
- PBX1 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV63347130; called by muse, mutect2, varscan2
- PCDH15 | c.4565G>A p.R1522K (on ENST00000617271 / NM_001142770.3; = p.K1510= on NM_001142769.3) | Missense Mutation (SNP) | VAF 40/161 reads (25%) | PolyPhen benign (0.006); catalogued as COSV64680988; called by muse, mutect2, varscan2
- PCDH15 | c.4766C>T p.P1589L | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as CD1515093, COSV57407512; called by muse, mutect2, varscan2
- PCDH15 | c.4591G>A p.E1531K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs867154687, COSV57284690, COSV57325635; called by muse, mutect2, varscan2
- PCDH15 | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759961676, COSV57407549; called by muse, mutect2, varscan2
- PCDHA8 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 80/121 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV65340908; called by muse, mutect2, varscan2
- PCDHB8 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV50828088; called by muse, mutect2, varscan2
- PCDHGA1 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV65296158; called by muse, mutect2, varscan2
- PCDHGA8 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV54049998; called by muse, mutect2, varscan2
- PCLO | c.11491C>T p.R3831C | Missense Mutation (SNP) | VAF 55/83 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61626253; called by muse, mutect2, varscan2
- PCLO | c.6794C>T p.S2265F | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs1185436297, COSV61621473; called by muse, mutect2, varscan2
- PCNX2 | c.4351G>A p.G1451R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50932120, COSV99268352; called by muse, mutect2
- PCNX2 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV50932785; called by muse, mutect2, varscan2
- PDE1C | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58531787; called by muse, mutect2, varscan2
- PDE1C | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58531808; called by muse, mutect2, varscan2
- PDE4D | c.1110G>T p.L370F (on ENST00000340635 / NM_001104631.2; = p.L234F on NM_006203.4) | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as COSV57716910, COSV57721231; called by muse, mutect2, varscan2
- PDE7B | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs867565541, COSV57508027; called by muse, mutect2, varscan2
- PDZRN3 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV55217851; called by muse, mutect2, varscan2
- PEX5 | c.1705C>T p.L569F (on ENST00000420616; = p.L561F on NM_000319.5) | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56958980; called by muse, mutect2, varscan2
- PHACTR4 | c.1073C>T p.T358I (on ENST00000373839 / NM_001350159.2; = p.T368I on NM_023923.4) | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV65785300; called by muse, mutect2, varscan2
- PHF14 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV68857678; called by muse, mutect2, varscan2
- PHLDB2 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV67316699; called by muse, mutect2, varscan2
- PI16 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as COSV65448911; called by mutect2, varscan2
- PIK3C2G | c.4252C>T p.R1418C (on ENST00000676171; = p.R1377C on NM_004570.5) | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs187869576, COSV56800156; called by muse, mutect2, varscan2
- PIP5K1B | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV55259625; called by muse, mutect2, varscan2
- PIWIL2 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV63252397; called by muse, mutect2, varscan2
- PKD1L1 | c.7798G>A p.D2600N | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51845494; called by muse, mutect2, varscan2
- PKHD1L1 | c.10623C>A p.S3541R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65746239, COSV65755377; called by muse, mutect2
- PLCB1 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV62067951, COSV62071491; called by muse, varscan2
- PLCG2 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs773116531, COSV63874047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCH1 | c.2456G>A p.R819Q (on ENST00000340059 / NM_001130960.2; = p.R831Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.902); catalogued as rs770441425, COSV58211553; called by muse, mutect2, varscan2
- PLCH1 | c.178G>A p.E60K (on ENST00000340059 / NM_001130960.2; = p.E72K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV58211575; called by muse, mutect2, varscan2
- PLEKHA5 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54714097; called by muse, mutect2, varscan2
- PLEKHN1 | c.1480G>A p.D494N (on ENST00000379409; = p.D442N on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV58024127; called by muse, mutect2, varscan2
- PLXDC2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV65909929; called by muse, mutect2, varscan2
- PLXNA1 | c.5321C>T p.S1774L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761304812, COSV52523994; called by muse, mutect2, varscan2
- PML | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.77); catalogued as rs1436188555, COSV51455402; called by muse, mutect2, varscan2
- PNMA2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV72908621; called by muse, mutect2, varscan2
- POLQ | c.4729C>T p.P1577S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV51763161; called by muse, mutect2, varscan2
- POLR2F | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV68092214; called by muse, varscan2
- PPP1R3A | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52877811; called by muse, mutect2, varscan2
- PPP1R3B | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV60099508; called by muse, mutect2, varscan2
- PPP2R2C | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.162); catalogued as COSV58677344; called by muse, mutect2, varscan2
- PPP6R3 | c.2134C>T p.P712S (on ENST00000393800 / NM_001352375.2; = p.P632S on NM_018312.5) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs768262130, COSV55737841; called by muse, mutect2, varscan2
- PRAM1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs890246858, COSV55315459; called by muse, mutect2, varscan2
- PRAMEF12 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1256401692, COSV63216087; called by muse, mutect2, varscan2
- PRDM9 | c.1119G>A p.W373* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as COSV57010649, COSV99691556; called by muse, mutect2, varscan2
- PRDM9 | c.1397G>C p.R466T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV57011096, COSV57012625; called by muse, mutect2
- PRKCG | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54734125; called by mutect2, varscan2
- PRKRIP1 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as rs1318287925, COSV61351015; called by muse, mutect2, varscan2
- PRKX | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs764562389, COSV53327327, COSV53328026; called by muse, mutect2, varscan2
- PRR23B | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV61495089; called by muse, mutect2, varscan2
- PRSS16 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs150849072; called by muse, mutect2, varscan2
- PRUNE2 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761404101, COSV65043365; called by muse, mutect2, varscan2
- PSD | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as rs768671841, COSV50067201; called by muse, mutect2, varscan2
- PSD2 | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV51214894; called by muse, mutect2, varscan2
- PSG6 | c.604T>C p.Y202H | Missense Mutation (SNP) | VAF 91/158 reads (58%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.544); catalogued as rs752804357, COSV51839049; called by muse, mutect2, varscan2
- PSG8 | c.430C>T p.L144= | Splice Region (SNP) | VAF 92/142 reads (65%) | catalogued as rs1466865677, COSV60610769; called by muse, mutect2, varscan2
- PSMA4 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99245376; called by muse, mutect2, varscan2
- PSME4 | c.4996C>T p.Q1666* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as COSV66368393; called by muse, mutect2, varscan2
- PTGDR | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs142969446; called by muse, mutect2, varscan2
- PTGIS | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as COSV54841244; called by muse, mutect2, varscan2
- PTGS2 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); catalogued as COSV66569313, COSV66569968; called by muse, mutect2
- PTPRH | c.3233G>A p.R1078Q | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV54742428, COSV99670655; called by muse, mutect2, varscan2
- PTPRH | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV54750903; called by muse, mutect2, varscan2
- PTPRN2 | c.2765C>T p.S922F | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101153404; called by muse, mutect2, varscan2
- PTPRT | c.2756G>A p.G919E | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.331); catalogued as COSV61978084; called by muse, varscan2
- PTPRT | c.2755G>A p.G919R | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1468460412; called by muse, varscan2
- PTPRT | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV62029572; called by muse, mutect2, varscan2
- PTX4 | c.223C>T p.R75W (on ENST00000447419 / NM_001328608.2; = p.R70W on NM_001013658.1) | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs755708029; called by muse, mutect2, varscan2
- PXDN | c.2479C>T p.H827Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53247904; called by muse, mutect2, varscan2
- QSER1 | c.4408C>T p.P1470S (on ENST00000399302; = p.P1599S on NM_001076786.3) | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV67901978; called by muse, mutect2, varscan2
- RAPGEF4 | c.2470C>T p.Q824* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | catalogued as COSV51418463; called by muse, mutect2, varscan2
- RARRES2 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 111/601 reads (18%) | catalogued as COSV56232268; called by muse, mutect2, varscan2
- RASAL2 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV62724740; called by muse, mutect2, varscan2
- RASGRF1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1232299457, COSV69183902; called by muse, mutect2, varscan2
- RBFOX1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765695547, COSV60953378; called by muse, mutect2, varscan2
- RBFOX1 | c.1072-1G>A p.X358_splice | Splice Site (SNP) | VAF 32/89 reads (36%) | catalogued as COSV100304251, COSV60987711; called by muse, mutect2, varscan2
- RBM19 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV55699822; called by muse, mutect2, varscan2
- RBM46 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55976738; called by muse, mutect2, varscan2
- RERE | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as rs866112189, COSV61952513; called by muse, varscan2
- RERG | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 134/223 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV57005889; called by muse, mutect2, varscan2
- RESF1 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as COSV57024683; called by muse, mutect2, varscan2
- RFX6 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60589390; called by muse, mutect2, varscan2
- RGL1 | c.398C>T p.S133L (on ENST00000360851 / NM_001297672.2; = p.S168L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as COSV58980702; called by muse, mutect2, varscan2
- RGS3 | c.2468C>T p.S823F (on ENST00000350696 / NM_001282923.2; = p.S542F on NM_130795.4) | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1189106159, COSV59523321; called by muse, mutect2, varscan2
- RGS7 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.597); catalogued as COSV58539993; called by muse, mutect2, varscan2
- RHCE | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1454592298, COSV53799752, COSV53803958, COSV99604527; called by muse, mutect2, varscan2
- RICTOR | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV57132003; called by muse, mutect2, varscan2
- RIMBP2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373251521; called by muse, mutect2, varscan2
- RIMS1 | c.98G>A p.R33K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53457223; called by muse, varscan2
- RIMS2 | c.1414G>A p.E472K (on ENST00000666250 / NM_001348490.2; = p.E280K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.993); catalogued as rs770388449, COSV51683310; called by muse, mutect2, varscan2
- RNF217 | c.1120C>T p.Q374* (on ENST00000521654 / NM_001286398.2; = p.Q82* on NM_152553.5) | Nonsense Mutation (SNP) | VAF 29/38 reads (76%) | catalogued as COSV51577940; called by muse, mutect2, varscan2
- ROS1 | c.3997G>A p.E1333K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV63862557; called by muse, mutect2, varscan2
- RP1 | c.2543G>A p.R848K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV55115836; called by muse, mutect2, varscan2
- RP1 | c.3352C>T p.H1118Y | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV55111043; called by muse, mutect2, varscan2
- RP1L1 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.171); catalogued as rs377751683; called by muse, varscan2
- RPE65 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV52019057; called by muse, mutect2, varscan2
- RPF2 | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV64371078; called by muse, mutect2, varscan2
- RPGRIP1L | c.3448C>T p.R1150W | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs750930363, COSV50902572; called by muse, mutect2, varscan2
- RPL4 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.53); catalogued as rs766526860, COSV57183802; called by muse, mutect2, varscan2
- RPS6KA1 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs758148586, COSV64809878; called by muse, mutect2, varscan2
- RPTN | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs746700515, COSV60169544; called by muse, mutect2, varscan2
- RSPO1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV62975572; called by muse, mutect2, varscan2
- RTN1 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs752220474, COSV50750570; called by muse, mutect2, varscan2
- RUSC2 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs950306578; called by muse, varscan2
- S1PR5 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as COSV61014730; called by muse, mutect2, varscan2
- SALL1 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868718687, COSV51753329, COSV51757244; called by muse, mutect2, varscan2
- SALL1 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51753505, COSV51765954; called by muse, mutect2, varscan2
- SALL3 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1255869339, COSV73306712; called by muse, mutect2, varscan2
- SAMD7 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV59418435; called by muse, mutect2, varscan2
- SAMD9 | c.3877C>T p.R1293W | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.68); catalogued as COSV66077982; called by muse, mutect2, varscan2
- SAMHD1 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53433059; called by muse, mutect2, varscan2
- SBF2 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56313739; called by muse, mutect2, varscan2
- SCLT1 | c.1357T>A p.F453I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV55405673, COSV55413861; called by muse, mutect2, varscan2
- SCN11A | c.4906G>A p.E1636K | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV56573976; called by muse, mutect2, varscan2
- SCN11A | c.4354C>T p.Q1452* | Nonsense Mutation (SNP) | VAF 19/24 reads (79%) | catalogued as COSV56572909; called by muse, mutect2, varscan2
915 further variants in this file (318 protein-altering or splice-affecting, 554 silent, 43 other) are not listed here.
